Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6UB, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6UB-01A (Primary Tumor).

Neuropathology

Commentary:

Histology and morphology correspond to oligodendroglioma WHO grade II.

Diagnosis:

Oligodendroglioma WHO grade II

CNF ICD-O-3
Oligodendroglioma
path grade II 9450/3
Oligodendroglioma NOS
9450/3
Site: Brain, supratentorial NOS
C71.0
9/25/13

untranslated original report
is housed at the BCR.

Source: NCI Genomic Data Commons file a409650f-5baf-4207-8c30-4234b7da3273 (TCGA-S9-A6UB.F71CEABA-8472-49C7-B618-47CDE4C43AC3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).